FM case AD15170 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/956a7586-edf6-41f7-a158-92984c1ded24

Male, 65.3 years: Duct adenocarcinoma, NOS (ICD-O-3 8500/3) of the pancreas; metastasis. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
